Somatic mutation profile of tumor specimen MP2PRT-PARVMM-TMP1-A (aliquot MP2PRT-PARVMM-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PARVMM, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 5.0 years (1,837 days).
Specimen MP2PRT-PARVMM-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 799ce009-2b45-4a26-9f37-dd28dda927b9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARVMM-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARVMM-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abce31d3-467e-4d85-9fcd-5483bd91e477

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 110/269 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ALDH3A1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 143/505 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs372399759; called by muse, mutect2, varscan2
- ARMC4 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 154/478 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs772563349; called by muse, mutect2, varscan2
- COLEC11 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 111/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1286607074; called by muse, mutect2, varscan2
- EPB41L3 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 101/322 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763472908, COSV100548889; called by muse, mutect2, varscan2
- MKX | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 90/395 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.946); catalogued as rs190790004, COSV65393300; called by muse, mutect2, varscan2
- MUC16 | c.19013C>T p.S6338L | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as rs769913294, COSV67454264; called by muse, mutect2
- POSTN | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 144/320 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.697); catalogued as rs1442280400; called by muse, mutect2, varscan2
- PTPRN2 | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 82/192 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.132); catalogued as rs749287887; called by muse, mutect2
- DGKB | c.1836T>A p.S612R | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HCN2 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 78/156 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- SH3TC2 | c.57A>G p.K19= | Silent (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
